Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EX, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EX-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, squamous cell NOS 867613
Site: Esophagus, middle third C15.4
JCS 1/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus (Mid third)

PATHOLOGY REPORT:

- 1 - "Esophagogastrectomy specimen":
- Specimen: esophagus and proximal stomach
- Procedure: esophagogastrectomy
- Tumor site: esophagus
- Tumor size (greatest dimension): 2.2 cm
- Histologic type: squamous cell carcinoma.
- Histologic grade: G2, moderately differentiated.
- Microscopic tumor extension: tumor invades through submucosa.
- Lymph-vascular invasion: not identified
- Perineural invasion: not identified
- Margins uninvolved by carcinoma
- Gastric mucosa uninvolved by carcinoma.
- Right paracardiac lymph nodes:
- Number examined: 02
- Number positive for neoplasia: 00
- Left paracardiac lymph nodes:
- Number examined: 12
- Number positive for neoplasia: 03
- Lesser curvature of the stomach lymph nodes:
- Number examined: 03
- Number positive for neoplasia: 00
- Celiac trunk lymph nodes:
- Number examined: 08
- Number positive for neoplasia: 02
- Inferior pancreatic lymph nodes:
- Number examined: 02
- Number positive for neoplasia: 01
- Supradiaphragmatic lymph nodes:
- Number examined: 02
- Number positive for neoplasia: 00
- 2 - "Esophageal margin":
- Uninvolved by carcinoma.

[page 2 of 2]
3 - "Hepatogastric ligament margin":

- Uninvolved by carcinoma.

4 - "Mediastinal lymph nodes":

- One lymph node involved by metastatic carcinoma (1/1).

5 - "Subcarinal lymph nodes":

- Two of four lymph nodes involved by metastatic carcinoma (2/4).

Source: NCI Genomic Data Commons file e47e5f2c-1ec3-4960-b5d1-07a69bbaeb53 (TCGA-VR-A8EX.8773AED6-B0D9-405A-8AB8-3BCCD8781AD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).